Surgical pathology report (de-identified scan), TCGA case TCGA-37-3783, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Cureline, specimen TCGA-37-3783-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Index	[REDACTED]				[REDACTED]	[REDACTED]
1					[REDACTED]	[REDACTED]
					[REDACTED]	[REDACTED]

[page 2 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container
[REDACTED]	Lung	Primary	Tumor	Tissue	OCT	block	1	n/a
[REDACTED]	Blood	n/a	Normal	Blood	frozen	tube	1	n/a

[page 3 of 4]
Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type
n/a	surgery	Squamous cell carcinoma	3	3	2	0	none
n/a	blood draw	n/a	n/a	n/a	n/a	n/a	none

[page 4 of 4]
[REDACTED]

[REDACTED]

Component of treatment (Chemo / Horm Th Details)	Tumor cell %
n/a	over 50
n/a	n/a

Source: NCI Genomic Data Commons file 44eb3e30-04d5-4786-9680-91c7b23b1864 (TCGA-37-3783.B3F279C3-F3A4-45A3-A711-B61873A3CA0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).